Somatic mutation profile of tumor specimen C3N-01334-03 (aliquot CPT0125220006) from CPTAC case C3N-01334, project CPTAC-3 (Brain — Gliomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 64.5 years (23,573 days).
Specimen C3N-01334-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Occipital Cortex; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 34a00ef8-2352-4a64-ba43-ebc1f95e5883.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01334-31 (Blood Derived Normal), aliquot CPT0125250002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/21de549e-e44e-4067-bd0d-dfcebb202737

The open-access MAF lists 87 somatic variants for this specimen: 49 protein-altering or splice-affecting, 24 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 42, Silent 24, Intron 5, RNA 4, Nonsense Mutation 2, 5'Flank 2, Frame Shift Del 2, 3'UTR 2, In Frame Del 2, 5'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.1793G>T p.G598V | Missense Mutation (SNP) | VAF 611/7492 reads (8%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs139236063, COSV51769031, COSV51808387; ClinVar: likely pathogenic; called by muse, mutect2
- AC133561.1 | n.2019+1G>A | Splice Site (SNP) | VAF 50/265 reads (19%) | catalogued as rs1316194210; called by muse, mutect2, varscan2
- AMPD1 | c.973C>T p.R325* | Nonsense Mutation (SNP) | VAF 110/407 reads (27%) | catalogued as rs143235944; called by muse, mutect2
- AP2A1 | c.2458G>A p.A820T | Missense Mutation (SNP) | VAF 40/152 reads (26%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.996); catalogued as COSV100571066; called by muse, mutect2, varscan2
- ARHGEF5 | c.1127C>T p.A376V | Missense Mutation (SNP) | VAF 46/383 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as rs1342949112; called by mutect2, varscan2
- BCL9 | c.2419G>T p.D807Y | Missense Mutation (SNP) | VAF 22/512 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs587607792, COSV52340431; called by muse, mutect2
- CACNA1F | c.2983G>A p.V995M | Missense Mutation (SNP) | VAF 119/405 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV59903168; called by muse, mutect2, varscan2
- CCDC88B | c.2450C>T p.A817V | Missense Mutation (SNP) | VAF 48/173 reads (28%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.994); catalogued as rs770315982; called by muse, mutect2, varscan2
- CPZ | c.833G>A p.R278H (on ENST00000360986 / NM_001014447.3; = p.R267H on NM_003652.3) | Missense Mutation (SNP) | VAF 26/264 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.017); catalogued as rs773276230; called by muse, mutect2, varscan2
- DHX34 | c.452G>A p.R151H | Missense Mutation (SNP) | VAF 64/272 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs149967464, COSV60898381; called by muse, mutect2, varscan2
- EPHA7 | c.917G>T p.G306V | Missense Mutation (SNP) | VAF 71/246 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.363); catalogued as rs768989326; called by muse, mutect2, varscan2
- FER1L6 | c.4699C>T p.R1567C | Missense Mutation (SNP) | VAF 73/215 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.391); catalogued as rs770028424, COSV67550136; called by muse, mutect2, varscan2
- FLG | c.10609T>A p.S3537T | Missense Mutation (SNP) | VAF 187/660 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs553691656; called by muse, mutect2, varscan2
- FLT4 | c.898G>A p.V300I | Missense Mutation (SNP) | VAF 144/563 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.429); catalogued as rs186187161, COSV56113216; called by muse, mutect2, varscan2
- HMGN5 | c.405_407del p.E135del | In Frame Del (DEL) | VAF 58/292 reads (20%) | catalogued as rs1307866910; called by pindel, varscan2
- KCND1 | c.1833G>C p.E611D | Missense Mutation (SNP) | VAF 111/362 reads (31%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.007); catalogued as rs868972833, COSV99501874; called by muse, mutect2, varscan2
- LGR5 | c.1853C>T p.A618V | Missense Mutation (SNP) | VAF 79/273 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.483); catalogued as rs751153165, COSV57005151; called by muse, mutect2, varscan2
- LGR6 | c.2056G>A p.V686I (on ENST00000367278 / NM_001017403.1; = p.V634I on NM_021636.3) | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.545); catalogued as rs376010617; called by muse, mutect2, varscan2
- MPHOSPH6 | c.325G>A p.V109M | Missense Mutation (SNP) | VAF 39/445 reads (9%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.982); catalogued as rs1408474947; called by muse, mutect2
- MYH15 | c.4240G>A p.E1414K | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.514); catalogued as rs749735364, COSV99842132; called by muse, varscan2
- OR10R2 | c.763C>T p.R255W | Missense Mutation (SNP) | VAF 68/275 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.082); catalogued as rs145324354; called by muse, mutect2, varscan2
- OSBPL6 | c.2702T>C p.V901A | Missense Mutation (SNP) | VAF 50/191 reads (26%) | SIFT tolerated (0.62); PolyPhen probably damaging (0.962); catalogued as rs1248107392; called by muse, mutect2, varscan2
- PLCB2 | c.533G>A p.R178H | Missense Mutation (SNP) | VAF 79/340 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs376517913; called by muse, mutect2, varscan2
- PSMC2 | c.562C>T p.R188* | Nonsense Mutation (SNP) | VAF 77/385 reads (20%) | catalogued as COSV99485433; called by muse, mutect2, varscan2
- RBMXL3 | c.391C>T p.R131C | Missense Mutation (SNP) | VAF 65/231 reads (28%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as rs782457452; called by muse, mutect2, varscan2
- SMCP | c.14C>A p.T5K | Missense Mutation (SNP) | VAF 87/287 reads (30%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0); catalogued as rs199812597; called by muse, mutect2, varscan2
- SSUH2 | c.482G>A p.R161H | Missense Mutation (SNP) | VAF 61/270 reads (23%) | SIFT tolerated (0.69); PolyPhen benign (0.015); catalogued as rs113259595, COSV58033018; called by muse, mutect2, varscan2
- ST8SIA3 | c.562C>T p.R188C | Missense Mutation (SNP) | VAF 75/227 reads (33%) | PolyPhen probably damaging (1); catalogued as rs1568101404, COSV60653938; called by muse, mutect2, varscan2
- TAF1 | c.2378G>A p.R793H (on ENST00000373790 / NM_138923.4; = p.R814H on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 57/198 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779799290, COSV52109146; called by muse, mutect2, varscan2
- TUT4 | c.1163C>T p.T388M | Missense Mutation (SNP) | VAF 93/341 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as rs1557851304; called by muse, mutect2, varscan2
- ZNHIT1 | c.46C>T p.R16W | Missense Mutation (SNP) | VAF 35/160 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.633); catalogued as rs771133778; called by muse, mutect2, varscan2
- ARMCX3 | c.195_200del p.D66_S67del | In Frame Del (DEL) | VAF 33/183 reads (18%) | called by mutect2, pindel, varscan2
- CCDC141 | c.568C>A p.Q190K | Missense Mutation (SNP) | VAF 72/260 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- DLX6 | c.421C>G p.R141G | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.428); called by muse, mutect2, varscan2
- EGFL6 | c.704A>G p.N235S | Missense Mutation (SNP) | VAF 54/208 reads (26%) | SIFT tolerated (0.33); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- EOMES | c.1229T>C p.V410A | Missense Mutation (SNP) | VAF 85/320 reads (27%) | SIFT tolerated (0.45); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- FAM47B | c.475C>G p.L159V | Missense Mutation (SNP) | VAF 58/176 reads (33%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.569); called by muse, mutect2, varscan2
- HMCN1 | c.11588T>C p.I3863T | Missense Mutation (SNP) | VAF 142/477 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- IFI16 | c.1903T>C p.Y635H (on ENST00000295809 / NM_001364867.2; = p.Y579H on NM_005531.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 71/313 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MRPL38 | c.663G>C p.L221F | Missense Mutation (SNP) | VAF 84/301 reads (28%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- OR56B1 | c.254C>T p.T85I | Missense Mutation (SNP) | VAF 140/477 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCSK1N | c.103C>T p.R35W | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.963); called by mutect2, varscan2
- PRR14L | c.2962_2965del p.S988Pfs*5 | Frame Shift Del (DEL) | VAF 54/420 reads (13%) | called by pindel, varscan2
- SHANK2 | c.4349C>T p.S1450L | Missense Mutation (SNP) | VAF 198/688 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SLC39A10 | c.601del p.I201Lfs*121 | Frame Shift Del (DEL) | VAF 110/400 reads (28%) | called by mutect2, pindel, varscan2
- SULF1 | c.2185G>A p.E729K | Missense Mutation (SNP) | VAF 38/185 reads (21%) | SIFT tolerated (0.92); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- WDFY4 | c.2354A>C p.K785T | Missense Mutation (SNP) | VAF 13/171 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0.006); called by muse, mutect2
- WDR81 | c.5384G>A p.S1795N (on ENST00000409644 / NM_001163809.2; = p.S744N on NM_152348.4) | Missense Mutation (SNP) | VAF 52/189 reads (28%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- ZBTB16 | c.1938G>C p.Q646H | Missense Mutation (SNP) | VAF 149/535 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- ABCB5 | c.550C>T p.L184= | Silent (SNP) | VAF 83/345 reads (24%) | called by muse, mutect2, varscan2
- ADRA1A | c.258C>T p.F86= | Silent (SNP) | VAF 63/422 reads (15%) | catalogued as rs1237521939, COSV52357792; called by muse, mutect2, varscan2
- ATP9A | c.1311G>A p.P437= | Silent (SNP) | VAF 55/228 reads (24%) | catalogued as rs371469001; called by muse, mutect2, varscan2
- BTNL3 | c.825C>T p.H275= | Silent (SNP) | VAF 32/294 reads (11%) | catalogued as rs970197016, COSV61564255; called by muse, mutect2, varscan2
- CACNA1F | c.4824C>T p.D1608= | Silent (SNP) | VAF 120/462 reads (26%) | catalogued as rs781955957, COSV59902789; called by muse, mutect2, varscan2
- DCD | c.303C>T p.D101= | Silent (SNP) | VAF 72/250 reads (29%) | catalogued as rs373661792; called by muse, mutect2, varscan2
- EEFSEC | c.399C>T p.I133= | Silent (SNP) | VAF 128/510 reads (25%) | catalogued as rs766788552; called by muse, mutect2, varscan2
- ERP27 | c.474C>T p.S158= | Silent (SNP) | VAF 77/255 reads (30%) | catalogued as rs756463054, COSV56764601; called by muse, mutect2, varscan2
- FAM189A1 | c.1071C>T p.P357= | Silent (SNP) | VAF 52/188 reads (28%) | catalogued as rs546175027; called by muse, mutect2, varscan2
- FRMPD4 | c.186C>T p.D62= | Silent (SNP) | VAF 57/192 reads (30%) | catalogued as rs1272484457, COSV66215587; called by muse, mutect2, varscan2
- KCNH2 | c.2751G>A p.P917= | Silent (SNP) | VAF 31/114 reads (27%) | catalogued as rs1404614771, CD097537; called by muse, mutect2, varscan2
- KIR3DL2 | c.321G>A p.S107= | Silent (SNP) | VAF 108/492 reads (22%) | catalogued as rs370791268; called by muse, mutect2, varscan2
- LRRC30 | c.192C>T p.P64= | Silent (SNP) | VAF 110/394 reads (28%) | catalogued as rs771985235, COSV101274385, COSV67301906; called by muse, mutect2, varscan2
- MAP3K19 | c.813G>A p.S271= | Silent (SNP) | VAF 12/148 reads (8%) | catalogued as rs772166646, COSV59638066; called by muse, mutect2
- MCMDC2 | c.987T>C p.S329= | Silent (SNP) | VAF 91/381 reads (24%) | called by muse, mutect2, varscan2
- MYO18B | c.6727C>T p.L2243= | Silent (SNP) | VAF 14/376 reads (4%) | called by muse, mutect2
- PMS2 | c.1107G>A p.K369= | Silent (SNP) | VAF 103/520 reads (20%) | catalogued as rs1554298683, COSV56223648; ClinVar: likely benign; called by muse, mutect2, varscan2
- POTEI | c.516A>G p.Q172= | Silent (SNP) | VAF 15/66 reads (23%) | called by mutect2, varscan2
- PXDNL | c.3318C>T p.G1106= | Silent (SNP) | VAF 61/216 reads (28%) | called by muse, mutect2, varscan2
- SLC6A5 | c.621C>T p.Y207= | Silent (SNP) | VAF 43/169 reads (25%) | catalogued as rs781151093; ClinVar: likely benign; called by muse, mutect2, varscan2
- SMURF2 | c.819G>A p.Q273= | Silent (SNP) | VAF 70/300 reads (23%) | called by muse, mutect2, varscan2
- SULT1E1 | c.576C>T p.Y192= | Silent (SNP) | VAF 52/143 reads (36%) | catalogued as rs775312926, COSV56946956; called by muse, mutect2, varscan2
- WDR17 | c.2946C>T p.R982= | Silent (SNP) | VAF 49/325 reads (15%) | catalogued as rs146440894; called by muse, mutect2, varscan2
- ZNF568 | c.1281G>A p.A427= | Silent (SNP) | VAF 18/228 reads (8%) | catalogued as rs780401558; called by muse, mutect2
- AC011525.1 | n.842C>T | RNA (SNP) | VAF 75/345 reads (22%) | catalogued as rs1281027754; called by muse, varscan2
- AC092471.1 | n.806G>T | RNA (SNP) | VAF 30/120 reads (25%) | catalogued as rs1296110262; called by muse, mutect2, varscan2
- ARNT | chr1:150876604 C>A | 5'Flank (SNP) | VAF 63/150 reads (42%) | catalogued as rs904716180; called by muse, mutect2, varscan2
- CDH15 | chr16:89168631 G>A | 5'Flank (SNP) | VAF 66/258 reads (26%) | catalogued as rs896618434; called by muse, mutect2, varscan2
- EPHX2 | c.-44C>T | 5'UTR (SNP) | VAF 27/140 reads (19%) | called by muse, mutect2, varscan2
- FOLH1B | n.1620C>T | RNA (SNP) | VAF 106/477 reads (22%) | catalogued as rs371957815; called by muse, mutect2, varscan2
- HERC2P3 | n.341C>T | RNA (SNP) | VAF 100/625 reads (16%) | catalogued as rs1415211884; called by muse, mutect2, varscan2
- INCENP | c.1605+31C>T | Intron (SNP) | VAF 80/279 reads (29%) | catalogued as rs752328058; called by muse, mutect2, varscan2
- KCTD15 | c.*363C>T | 3'UTR (SNP) | VAF 38/116 reads (33%) | catalogued as rs1408832448; called by muse, mutect2, varscan2
- KRT80 | c.571-44C>T | Intron (SNP) | VAF 5/52 reads (10%) | catalogued as rs1449546914; called by muse, mutect2
- MAMLD1 | c.*1091A>C | 3'UTR (SNP) | VAF 40/132 reads (30%) | called by muse, mutect2, varscan2
- MEGF11 | c.2711-2911G>A | Intron (SNP) | VAF 75/202 reads (37%) | catalogued as rs1356108834, COSV56554875; called by muse, mutect2, varscan2
- MSLNL | c.37+1350C>T | Intron (SNP) | VAF 20/153 reads (13%) | catalogued as rs543553066, COSV50099878; called by muse, mutect2, varscan2
- PTPRN2 | c.2344+5900G>A | Intron (SNP) | VAF 73/355 reads (21%) | catalogued as rs545943446, COSV67043405; called by muse, mutect2, varscan2
